Gene-level copy-number profile of tumor specimen TARGET-10-PAPBES-03A from TARGET case TARGET-10-PAPBES, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (812 days).
Specimen TARGET-10-PAPBES-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.265cc0ff-cb35-53a4-9e4d-eaf00942ea8e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PAPBES-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/333f7b65-ed68-42cf-a116-43cfe393f07a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 2: 39,415; copy number 3: 20,089; copy number 4: 11; copy number 5: 737; copy number 7: 6; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,935,456–56,055,730, 9 genes: OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1, OR5AQ1P.
- chr14:22,438,547–22,450,139, 4 genes: TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 744 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:166,098,111–166,099,589, 1 gene, copy number 5: AL627443.3.
- chr6:166,099,853–166,099,924, 1 gene, copy number 5: AL627443.2.
- chr10:133,453,928–133,569,835, 6 genes, copy number 7 (within-gene range 3–7): SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1.
- chr17:41,271,311–41,271,835, 1 gene, copy number 10: KRTAP9-11P.
- chr21:12,999,676–46,665,124, 735 genes, copy number 5 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
